Surgical pathology report (de-identified scan), TCGA case TCGA-VF-A8AC, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Pennsylvania, specimen TCGA-VF-A8AC-01A (Primary Tumor).

[page 1 of 4]
Panel: Surgical Pathology Report

Date: 1 /

- Abnormal Flags key: C Critical H High L Low R Review * Abnormal
- Interpretation Codes: (S) Susceptible (R) Resistant (MS) Moderately Susceptible (I) Intermediate
- Status codes: P-Preliminary F-Final C-Corrected I-In progress/incomplete X-Cancelled
- Dates and times displayed below are collection dates; to see the observation date and time for a result, hold your course over the collection time. Times are on a 24-hour clock.
- An asterisk [*] in the Note column or next to a panel name indicates a note is present. To view it, rest your mouse cursor on the [*].

Panel	Accession #	Collected	Value	Units	Range	Note
Surgical Pathology Report	XXXXXXXXXX F	XXXXXXXXXX	XXXXXXXXXX			
Collection d/t:						

Obs d/t:
Ordered by:

Surgical Pathology Report

ICD-O 3
Seminoma NOS 9061/3
Site: B Testis NOS 9062.9
4/05/2014

Final Diagnosis

- Testicle, right; orchiectomy:
- Classical seminoma, confined to the testis, see synoptic summary.
- Tumor measures 1.3 cm in greatest dimension, grossly.
- Tumor involves rete testes, but not the epididymis or tunica vaginalis.
- No lymphovascular invasion seen.
- Adjacent seminiferous tubules with intratubular germ cell neoplasia and atrophy.
- Spermatic cord, vascular, and soft tissue margins are free of tumor

The case material was reviewed and the report verified by:

(Electronic signature)

Verification Date:

Synoptic Report

1: Testis, Radical Orchiectomy Summary

SERUM TUMOR MARKERS:

Serum marker studies within normal limits

SPECIMEN LATERALITY:

Left

TUMOR FOCALITY:

Unifocal

TUMOR SIZE:

Greatest dimension of main tumor mass: 1.3 cm

MACROSCOPIC EXTENT OF TUMOR:

[page 2 of 4]
Confined to the testis
HISTOLOGIC TYPE:
Seminoma, classic type
SPERMATIC CORD MARGIN:
Uninvolved by tumor
MICROSCOPIC TUMOR EXTENSION:
Rete testis
LYMPH-VASCULAR INVASION:
Absent
PRIMARY TUMOR (pT):
pT1: Tumor limited to the testis and epididymis without vascular/lymphatic invasion; tumor may invade tunica albuginea but not tunica vaginalis
REGIONAL LYMPH NODES (pN):
pNX: Cannot be assessed
DISTANT METASTASIS (pM):
Not applicable
SERUM TUMOR MARKER(S):
SG: Serum marker study levels within normal limits
ADDITIONAL PATHOLOGIC FINDINGS:

None identified

Pathologist(s)

Gross Description

Specimen #1 designated "left testicle" is received fresh, labeled with the patient's name and medical record number and consists of a 35.7 g testicle with attached spermatic cord and soft tissue measuring 18.0 x 4.2 x 1.0 cm altogether. The testicle itself measures 4.5 x 3.5 x 1.0 cm and the attached spermatic cord and surrounding soft tissue measure 12.5 x 0.2 cm. The external surface of the specimen is inked entirely in green. The testicle is then bivalved to reveal a well-circumscribed, ovoid, firm, tan mass measuring 1.3 x 1.2 x 1.1 cm. . Representative sections are submitted as follows: 1A, vascular margin; 1B through 1G, the mass and surrounding testicular tissue submitted in toto; 1H, unremarkable testicle; 1I, rete testes; 1J, additional vasculature; 1K, spermatic cord margin.

SUMMARY OF SECTIONS: 13, multiple, representative

Dictated by:

Clinical Information

Left testicular mass

Pre-Operative Diagnosis: Not specified

Post-Operative Diagnosis: Not specified

[page 3 of 4]
Operation: Left orchiectomy
Specific questions to be answered: None

Specimen:

1 Testis, Tumor, Left

*** End of report ***

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form 4.05

Study Subject ID:		Person ID:	N/A
Study/Site:	TCGA Testicular Germ Cell Tumors - Tumors)	Age:	N/A
Event:	PathDiscrepancy	Date of Birth:	
Interviewer:		Sex:	M

Tumor Identifier Provided on Initial Case Quality Control Form

Provide the tumor identifier documented on the initial case quality control form for this case.

Pathologic Diagnosis Provided on Initial Pathology Report

Seminoma Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.

Histologic features of the sample provided for TCGA, as reflected on the CQCF

Classical seminoma

Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form

Left laterality confirmed

Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.

Name of TSS Reviewing Pathologist or Biorepository Director

Provide the name of the pathologist who reviewed this case for TCGA.

Source: NCI Genomic Data Commons file c6b684da-113b-4078-8daa-945ab81418dc (TCGA-VF-A8AC.EADFD7B1-3BE9-4DD1-A83A-C68F6E2AF194.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).